Gene-level copy-number profile of tumor specimen TCGA-3B-A9HQ-01A from TCGA case TCGA-3B-A9HQ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.8 years (24,386 days).
Specimen TCGA-3B-A9HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ffbd85c9-1aa0-40f0-8d3a-f108d6708b79.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d61d8d2f-59f2-4b7d-8ed9-71ecc7341eab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,583; copy number 2: 42,711; copy number 3: 7,507; copy number 5: 3; copy number 20: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HQ-01A-11D-A386-01): tumor purity 0.78, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:39,329,990–39,725,408, 1 gene, copy number 5 (within-gene range 2–5): KIF6.
- chr6:39,553,811–39,620,464, 2 genes, copy number 5: E2F4P1, RNU1-54P.
- chr17:12,665,890–13,100,939, 10 genes, copy number 20: MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1.

Autosomal genes at a single copy (total copy number 1): 9,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
